TARGET case TARGET-40-NAAEDA — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of other and unspecified sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1b4caa9f-c805-5034-b710-726f39748d89

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 9 years; Vital status: Dead; Days to death: 503 days (1.4 years).

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C41.4; Tissue or organ of origin: Pelvic bones, sacrum, coccyx and associated joints; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 9.5 years (3,464 days); Year of diagnosis: 2005; Metastasis at diagnosis: Metastasis, NOS; Days to last follow up: 503 days (1.4 years); Sites of involvement: Lung, NOS.
   Pathology details: Necrosis percent: 38.
   Treatment given: Protocol identifier: GBCTTO/99.
   Treatment given: Therapeutic agents: Cisplatin.
   Treatment given: Therapeutic agents: Doxorubicin.
   Treatment given: Therapeutic agents: Ifosfamide.
   Treatment given: Therapeutic agents: Mesna.

Follow-up (3 entries)
- Days to follow up: 359 days; Days to first event: 359 days; First event: Relapse.
- Days to follow up: 373 days (1.0 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 373 days (1.0 years).
- Days to follow up: 503 days (1.4 years); Progression or recurrence: Yes; Progression or recurrence type: Local; Year of follow up: 2006.

Biospecimens (3 samples)
- Sample TARGET-40-NAAEDA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-NAAEDA-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
- Sample TARGET-40-NAAEDA-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-NAAEDA-06A-01:
- Specimen Type: frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 25
- % Non Tumor Nuclei: Top from Biopsy: 75
- % Cellular Tumor: Top from Biopsy: 55*
- % Normal: Top from Biopsy: 45
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 0
- % Tumor Nuclei: Bottom from Biopsy: 10
- % Non Tumor Nuclei: Bottom from Biopsy: 90
- % Cellular Tumor: Bottom from Biopsy: 75*
- % Normal: Bottom from Biopsy: 25
- % Stroma: Bottom from Biopsy: 0
- % Necrosis: Bottom from Biopsy: 0
- PASS/FAIL: fail

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-NAAEDA-08A-01:
- Specimen Type: frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 90
- % Non Tumor Nuclei: Top from Biopsy: 10
- % Cellular Tumor: Top from Biopsy: 50*
- % Normal: Top from Biopsy: 50
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 0
- % Tumor Nuclei: Bottom from Biopsy: 90
- % Non Tumor Nuclei: Bottom from Biopsy: 10
- % Cellular Tumor: Bottom from Biopsy: 60*
- % Normal: Bottom from Biopsy: 40
- % Stroma: Bottom from Biopsy: 0
- % Necrosis: Bottom from Biopsy: 0
- PASS/FAIL: pass

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 503
- Metastasis site: Lung only
- Primary tumor site: Pelvis
- Specific tumor site: Pelvis
- Definitive Surgery: Limb sparing
- Primary site progression: Yes
- Site of initial relapse: Lung
- Time to first relapse in days: 373
- Time to first enrollment on relapse protocol in days: 130
- Time to first SMN in days: 0
- Histologic response: Stage 1/2 (0-90 % necrosis)
- Percent necrosis at Definitive Surgery: 37.5
- Relapse Type: Systemic, Locally recurrent
- Therapy: CDDP+ Doxo+ IFO +Mesna
